TCGA case TCGA-WK-A8XY — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01c5f902-ec3c-4eb7-9e38-1d29ae6ab959

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 1,991 days (5.5 years).

Diagnoses (5)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 53.7 years (19,597 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Contiguous organ invaded: Colon; Sites of involvement: Scalp / Colon, NOS; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 30.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 25; Tumor length measurement: 30; Tumor width measurement: 19.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 32.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 32.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 53.9 years (19,700 days); Days to diagnosis: 103 days; Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Abdomen, NOS. Age at diagnosis: 53.9 years (19,700 days); Days to diagnosis: 103 days; Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 53.9 years (19,700 days); Days to diagnosis: 103 days; Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 57.8 years (21,126 days); Days to diagnosis: 1,529 days (4.2 years); Prior treatment: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 4.1.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 103 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 103 days.
- Day 103 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 103 days.
- Day 103 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 103 days.
- Day 1,529 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 1,529 days (4.2 years).
- Days to follow up: 1,991 days (5.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 17.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-WK-A8XY-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Site of primary tumor other: Mesentery; Margin status: Positive; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: Yes; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Scalp; Contiguous organ invaded: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Small Intestines; Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,991 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,991 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 103 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WK-A8XY-01A-11D-A37B-01): tumor purity 0.93, ploidy 1.69, whole-genome doublings 0.
